Somatic mutation profile of tumor specimen TARGET-30-PAPKXS-01A (aliquot TARGET-30-PAPKXS-01A-01D) from TARGET case TARGET-30-PAPKXS, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 7.0 years (2,547 days).
Specimen TARGET-30-PAPKXS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0696eb47-d903-4b33-85ad-7c5309a7a2e5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAPKXS-10A (Blood Derived Normal), aliquot TARGET-30-PAPKXS-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f9933262-2d33-4eef-930a-35b43ddaf605

The open-access MAF lists 53 somatic variants for this specimen: 33 protein-altering or splice-affecting, 20 silent.
By variant classification: Missense Mutation 29, Silent 20, Frame Shift Ins 1, Nonsense Mutation 1, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA8 | c.3383del p.L1128* | Frame Shift Del (DEL) | VAF 8/76 reads (11%) | catalogued as COSV52209897; called by mutect2, pindel, varscan2
- ANKS4B | c.167G>T p.G56V | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61139006; called by muse, mutect2, varscan2
- ARHGAP32 | c.2857C>T p.P953S (on ENST00000310343 / NM_001378025.1; = p.P604S on NM_014715.4) | Missense Mutation (SNP) | VAF 75/171 reads (44%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as COSV59845747; called by muse, mutect2, varscan2
- CCDC89 | c.37A>T p.R13W | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.044); catalogued as COSV57033791; called by muse, varscan2
- GPRIN3 | c.1179C>G p.H393Q | Missense Mutation (SNP) | VAF 51/124 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.229); catalogued as COSV60884564; called by muse, mutect2, varscan2
- HSPA4 | c.2504C>G p.P835R | Missense Mutation (SNP) | VAF 45/93 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV59182113; called by muse, mutect2, varscan2
- IL12RB1 | c.1841A>T p.Q614L | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.049); catalogued as COSV74045456; called by muse, mutect2
- IL1RAPL1 | c.1877G>A p.R626Q | Missense Mutation (SNP) | VAF 9/11 reads (82%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.776); catalogued as COSV56239630; called by muse, mutect2, varscan2
- IL21 | c.438G>T p.K146N | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV52645781; called by muse, mutect2, varscan2
- KANK1 | c.17A>T p.K6M | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.319); catalogued as COSV63211292; called by muse, mutect2, varscan2
- LTBP1 | c.3553G>T p.D1185Y (on ENST00000404816 / NM_206943.4; = p.D859Y on NM_000627.4) | Missense Mutation (SNP) | VAF 22/160 reads (14%) | SIFT tolerated (0.67); PolyPhen benign (0.392); catalogued as COSV55377871; called by muse, mutect2, varscan2
- MAP2K7 | c.308C>T p.T103M | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.194); catalogued as rs769867905, COSV67609065; called by muse, mutect2
- MGA | c.6715A>G p.T2239A (on ENST00000219905 / NM_001164273.1; = p.T2030A on NM_001080541.2) | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.444); catalogued as COSV54951635; called by muse, mutect2, varscan2
- NCAN | c.1960G>A p.A654T | Missense Mutation (SNP) | VAF 56/103 reads (54%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV53049021; called by muse, mutect2, varscan2
- NEK5 | c.131A>T p.E44V | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62879490; called by muse, mutect2, varscan2
- NUP205 | c.5531A>T p.E1844V | Missense Mutation (SNP) | VAF 65/90 reads (72%) | SIFT tolerated (0.12); PolyPhen benign (0.198); catalogued as COSV53657298; called by muse, mutect2, varscan2
- OR2G2 | c.148C>A p.L50M | Missense Mutation (SNP) | VAF 90/187 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.894); catalogued as COSV60740011; called by muse, mutect2, varscan2
- PGM2L1 | c.1391T>C p.L464P | Missense Mutation (SNP) | VAF 77/157 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV53346086; called by muse, mutect2, varscan2
- PLA2G4A | c.292A>G p.M98V | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as rs546723218, COSV66553065; called by muse, mutect2, varscan2
- PLSCR4 | c.890C>T p.P297L | Missense Mutation (SNP) | VAF 35/68 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs762797844, COSV61607707; called by muse, varscan2
- PPP2R5B | c.53G>T p.G18V | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV51209697; called by muse, mutect2, varscan2
- RMI1 | c.1130dup p.N377Kfs*4 | Frame Shift Ins (INS) | VAF 12/37 reads (32%) | catalogued as rs1478572501; called by mutect2, varscan2
- ROBO3 | c.3796G>A p.D1266N | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as COSV100127840, COSV60622878; called by muse, mutect2, varscan2
- SLFN5 | c.841C>T p.L281F | Missense Mutation (SNP) | VAF 19/360 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as rs771296686; called by muse, mutect2
- TAT | c.1293C>A p.C431* | Nonsense Mutation (SNP) | VAF 5/60 reads (8%) | catalogued as COSV100587612; called by muse, mutect2
- TRIM47 | c.1102G>A p.A368T | Missense Mutation (SNP) | VAF 30/189 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV54668069; called by muse, mutect2, varscan2
- USP3 | c.824A>C p.E275A | Missense Mutation (SNP) | VAF 42/87 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV51426875; called by muse, mutect2, varscan2
- WBP1 | c.779G>T p.G260V | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.517); catalogued as COSV51968806; called by mutect2, varscan2
- COL4A1 | c.3550G>A p.D1184N | Missense Mutation (SNP) | VAF 9/120 reads (8%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.968); called by muse, mutect2
- GPR179 | c.4887_4895del p.E1629_E1631del (on ENST00000621958; = p.E1628_E1630del on NM_001004334.4) | In Frame Del (DEL) | VAF 178/275 reads (65%) | called by mutect2, pindel, varscan2
- POLDIP3 | c.1077G>C p.Q359H | Missense Mutation (SNP) | VAF 19/250 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- RELN | c.9950C>G p.A3317G | Missense Mutation (SNP) | VAF 108/154 reads (70%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- RELN | c.9949G>A p.A3317T | Missense Mutation (SNP) | VAF 111/156 reads (71%) | SIFT tolerated (0.12); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- BCAS1 | c.852T>C p.N284= | Silent (SNP) | VAF 4/70 reads (6%) | catalogued as rs1568856836; called by muse, mutect2
- BMP3 | c.915A>T p.A305= | Silent (SNP) | VAF 22/49 reads (45%) | catalogued as COSV51082598; called by muse, mutect2, varscan2
- CDHR3 | c.1467C>T p.D489= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV58415587, COSV58421811; called by muse, mutect2, varscan2
- DNAH7 | c.5424C>A p.S1808= | Silent (SNP) | VAF 26/65 reads (40%) | catalogued as COSV56758788; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.1026T>G p.S342= | Silent (SNP) | VAF 57/115 reads (50%) | catalogued as COSV57515378; called by muse, mutect2, varscan2
- GLIS3 | c.1218C>T p.H406= | Silent (SNP) | VAF 15/92 reads (16%) | catalogued as rs1315308272, COSV60927042; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1878A>T p.R626= | Silent (SNP) | VAF 9/11 reads (82%) | called by muse, mutect2, varscan2
- KIF2B | c.312G>A p.S104= | Silent (SNP) | VAF 71/392 reads (18%) | catalogued as rs543663752, COSV52129067, COSV52133640; called by muse, mutect2, varscan2
- LAMP2 | c.846A>T p.L282= | Silent (SNP) | VAF 80/86 reads (93%) | catalogued as COSV52352317; called by muse, mutect2, varscan2
- MYO3A | c.2023A>C p.R675= | Silent (SNP) | VAF 23/110 reads (21%) | catalogued as COSV56325850, COSV99780323; called by muse, mutect2, varscan2
- MYPN | c.1947C>A p.P649= | Silent (SNP) | VAF 20/46 reads (43%) | catalogued as COSV62732733; called by mutect2, varscan2
- N4BP2L1 | c.339C>G p.P113= | Silent (SNP) | VAF 43/102 reads (42%) | catalogued as COSV58412471; called by muse, mutect2, varscan2
- OR2T12 | c.615C>G p.L205= | Silent (SNP) | VAF 39/89 reads (44%) | catalogued as COSV58776979; called by muse, mutect2, varscan2
- PAPPA2 | c.2790C>T p.A930= | Silent (SNP) | VAF 59/131 reads (45%) | catalogued as COSV62794424; called by muse, mutect2, varscan2
- PIK3CB | c.1734G>T p.L578= | Silent (SNP) | VAF 257/590 reads (44%) | catalogued as COSV56684750; called by muse, mutect2, varscan2
- PPP2R5B | c.54G>T p.G18= | Silent (SNP) | VAF 6/12 reads (50%) | called by muse, mutect2, varscan2
- TAPBP | c.480T>C p.T160= | Silent (SNP) | VAF 14/26 reads (54%) | catalogued as rs1371576684, COSV70456961; called by mutect2, varscan2
- TF | c.1806G>A p.P602= | Silent (SNP) | VAF 105/204 reads (51%) | catalogued as rs200899169, COSV53919383; called by muse, mutect2, varscan2
- URI1 | c.354G>A p.E118= | Silent (SNP) | VAF 56/124 reads (45%) | catalogued as COSV56349060; called by muse, mutect2, varscan2
- ZNF786 | c.1896G>T p.V632= | Silent (SNP) | VAF 96/137 reads (70%) | catalogued as COSV60275594; called by muse, mutect2, varscan2
